Surgical pathology report (de-identified scan), TCGA case TCGA-XE-AAO4, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site University of Southern California, specimen TCGA-XE-AAO4-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY TISSUE REPORT

ICD-0-3

Seminoma NOS 9061/3

Site Testes NOS 1629

9/23/14

Name:

- Specimen Source:
- Gross Exam Date:
- Physician:

Pager No.:

DIAGNOSIS (based on GROSS and MICROSCOPIC examination):

1. SEMINOMA (1.7 cm), left testis, left radical orchiectomy. (See note)
2. NO LYMPHOVASCULAR INVASION NOTED. (See note)
3. NO INVASION OF EPIDIDYMIS NOTED.
4. TUMOR LIMITED TO TESTIS.
5. MARGINS FREE OF TUMOR.
6. PT1NXMX
7. TESTICULAR TISSUE WITH EVIDENCE OF SPERMATOGENESIS.

Note: Although carry over artifact is evident and occasionally involves the vessels, no definitive lymphovascular invasion is noted.

GROSS DESCRIPTION:

The specimen is received in one part, unfixed, labeled with the patient's name, and "left testicle and cord". It consists of a 40 gram orchiectomy specimen including 4.4x2.7x2.5 cm testes, 4.3 cm in length and 0.6 cm in diameter epididymis and 10.7 cm in length and 1.4 cm in diameter spermatic cord. 0.2 cm from the base of the epididymis and less than 0.1 cm from the tunica albuginea, there is a 1.7x1.4x1.4 cm tan-white fleshy lobulated well-circumscribed mass. There are no areas of hemorrhage or necrosis. There is no gross involvement of the tunica albuginea or impingement on the epididymis. The remaining testicular parenchyma is grossly unremarkable. The spermatic cord consists of vas deferens, arteries and veins. It is unremarkable. Representative sections are submitted.

SUMMARY OF CASSETTES:

- Cassettes #1 and #2 - tumor.
- Cassette #3 - tumor and adjacent testes.
- Cassette #4 - tumor and base of epididymis.

IN PT. ☐ COST CODE	CLINIC/WARD/NURSING STATION	PATIENT IDENTIFICATION
---	-----------------------------	------------------------

SURGICAL PATHOLOGY TISSUE REPORT

[page 2 of 2]
SURGICAL PATHOLOGY TISSUE REPORT

Name:

Operati

- Specimen Source: L TESTICLE AND CORD
- Gross Exam Date:
- Physician:

Pager No.:

Cassette #5 - tumor and tunica vaginalis.
Cassette #6 - spermatic cord resection margin.
Cassette #7 - spermatic cord mid-portion.
Cassette #8 - paratesticular portion.
R8.

IN PT. ☐ COST CODE	CLINIC/WARD/NURSING STATION	PATIENT IDENTIFICATION
---	-----------------------------	------------------------

SURGICAL PATHOLOGY TISSUE REPORT

PAGE 2

Source: NCI Genomic Data Commons file b20cfd74-a395-43b1-b1f0-9b0095f69fc4 (TCGA-XE-AAO4.054E28C1-12C8-4651-B532-5AF8DD15B1F8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).